Somatic mutation profile of tumor specimen TCGA-FD-A6TH-01A (aliquot TCGA-FD-A6TH-01A-11D-A32B-08) from TCGA case TCGA-FD-A6TH, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 63.6 years (23,236 days).
Specimen TCGA-FD-A6TH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 212a0924-bfe1-466b-8290-74d3e958bcb6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A6TH-10A (Blood Derived Normal), aliquot TCGA-FD-A6TH-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/566c1915-e679-46db-9ce4-3e0520ccb1d3

The open-access MAF lists 177 somatic variants for this specimen: 132 protein-altering or splice-affecting, 42 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 120, Silent 42, Nonsense Mutation 6, Frame Shift Ins 3, Splice Site 2, RNA 2, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.2966C>T p.T989I | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.809); catalogued as COSV70030421; called by muse, mutect2, varscan2
- ABCB5 | c.2659A>G p.I887V (on ENST00000404938 / NM_001163941.2; = p.I442V on NM_178559.6) | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1302856429, COSV51710841; called by muse, mutect2, varscan2
- ABCC8 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs761757944, CM118599, COSV56846669, COSV56847939, COSV56857898; called by muse, mutect2, varscan2
- ADAMTS20 | c.3284G>A p.G1095E | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769482588, COSV67132512; called by muse, mutect2, varscan2
- AKAP13 | c.2342C>T p.S781L | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.276); catalogued as rs530733643, COSV63456411; called by muse, mutect2, varscan2
- AKAP3 | c.602G>A p.R201K | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV57417204; called by muse, mutect2
- ANK2 | c.8395G>A p.D2799N | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.079); catalogued as rs374145576; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3431G>A p.R1144Q | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as COSV51848320; called by muse, mutect2, varscan2
- ARFGEF1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as COSV51609497; called by muse, mutect2, varscan2
- ASPHD2 | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV53219249, COSV99313288; called by muse, mutect2, varscan2
- CACNA1E | c.3040G>C p.E1014Q | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100701299, COSV62404961; called by muse, mutect2
- CACNG8 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV54414940, COSV54416630; called by muse, mutect2, varscan2
- CAD | c.6568G>A p.E2190K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53027382; called by muse, mutect2, varscan2
- CDKL3 | c.1519G>C p.E507Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV54742031; called by muse, mutect2, varscan2
- CEP95 | c.2158G>T p.E720* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV101616291; called by muse, mutect2, varscan2
- CER1 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as COSV101097885, COSV66603380; called by muse, mutect2, varscan2
- CFAP20DC | c.2395C>G p.L799V (on ENST00000482387 / NM_001351530.2; = p.L548V on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55920888; called by muse, mutect2, varscan2
- CIC | c.2726C>A p.P909Q | Missense Mutation (SNP) | VAF 67/481 reads (14%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV50579769, COSV50626735; called by muse, mutect2, varscan2
- CLINT1 | c.1632G>C p.L544F | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.277); catalogued as COSV51624908; called by muse, mutect2, varscan2
- CLPTM1 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV61612053; called by muse, mutect2, varscan2
- CNGA2 | c.1969G>C p.E657Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.034); catalogued as COSV61704773; called by muse, mutect2, varscan2
- CPEB3 | c.1304G>A p.R435Q | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.884); catalogued as rs754639698, COSV56457112; called by muse, mutect2, varscan2
- CREBRF | c.745C>T p.R249W | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.733); catalogued as rs377679411; called by muse, mutect2, varscan2
- CSMD3 | c.6553C>G p.Q2185E (on ENST00000297405 / NM_001363185.1; = p.Q2081E on NM_052900.3) | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV52090585, COSV52195233; called by muse, mutect2, varscan2
- CTDNEP1 | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.298); catalogued as rs759399442, COSV56642158; called by muse, mutect2, varscan2
- CUL1 | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 43/75 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.31); catalogued as COSV57388811; called by muse, mutect2, varscan2
- CYLC2 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as rs753247753, COSV66336189; called by muse, mutect2, varscan2
- DDX39A | c.1172C>T p.S391F | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs777641117, COSV54391872; called by muse, mutect2, varscan2
- DHX57 | c.1018G>C p.D340H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV54885858, COSV54891955; called by muse, mutect2, varscan2
- DNAH11 | c.2000T>C p.L667S | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as COSV60958240; called by muse, mutect2, varscan2
- DNAH5 | c.1197+1G>C p.X399_splice | Splice Site (SNP) | VAF 11/65 reads (17%) | catalogued as COSV54228639; called by muse, varscan2
- DYNC1LI1 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.224); catalogued as rs929220885, COSV56127637; called by muse, mutect2, varscan2
- DZIP3 | c.958G>A p.G320S | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as rs1349178205, COSV64312261; called by muse, mutect2, varscan2
- E2F7 | c.2018C>T p.S673F | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (0.7); PolyPhen benign (0.014); catalogued as COSV59740478; called by muse, mutect2, varscan2
- EEF1AKNMT | c.487C>G p.Q163E (on ENST00000361735 / NM_015935.5; = p.Q77E on NM_014955.3) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62283170; called by muse, mutect2, varscan2
- EPHA3 | c.1771C>G p.P591A | Missense Mutation (SNP) | VAF 62/115 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60708352; called by muse, mutect2, varscan2
- ESPNL | c.2951G>A p.G984D | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV58035045; called by muse, mutect2
- EVL | c.460G>A p.E154K (on ENST00000402714 / NM_001330221.2; = p.E156K on NM_016337.3) | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV67374298, COSV67374616, COSV67375575; called by muse, mutect2, varscan2
- EYA2 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV57944179; called by muse, mutect2, varscan2
- EYS | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV60987267; called by muse, mutect2, varscan2
- FAM110B | c.128C>A p.P43H | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.885); catalogued as COSV64065451; called by muse, mutect2, varscan2
- FAT3 | c.12516C>G p.F4172L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.712); catalogued as COSV99962290; called by muse, mutect2, varscan2
- FLNC | c.3014C>T p.S1005L | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs752448040, COSV57951263; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXN2 | c.78G>C p.Q26H | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1032352094, COSV61317113, COSV61318322; called by muse, mutect2, varscan2
- GABRA1 | c.1001T>A p.V334E | Missense Mutation (SNP) | VAF 102/133 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50106194; called by muse, mutect2, varscan2
- GRB14 | c.602T>C p.M201T | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV55738638; called by muse, mutect2, varscan2
- GRM8 | c.2453T>G p.L818R | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV58829629, COSV58836480; called by muse, mutect2, varscan2
- IGF2R | c.296C>G p.S99C | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.607); catalogued as rs756743378, COSV63628780; called by muse, mutect2, varscan2
- IGHMBP2 | c.1262G>A p.S421N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1269264954, COSV99661822; called by muse, mutect2, varscan2
- INTS9 | c.883G>A p.V295M | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777867933, COSV68434301; called by muse, mutect2
- IQCN | c.2189A>C p.Q730P | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as COSV66574617; called by muse, mutect2, varscan2
- JMJD6 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs1325653364, COSV57971821, COSV57972254, COSV57972715; called by muse, mutect2, varscan2
- KAT2A | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs147662719; called by muse, mutect2, varscan2
- KCNJ13 | c.456C>G p.I152M | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.709); catalogued as COSV99289228; called by muse, mutect2
- KIF26B | c.1371C>G p.I457M | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV100831661, COSV100831842; called by muse, mutect2
- KMT2A | c.11312+1G>A p.X3771_splice | Splice Site (SNP) | VAF 10/56 reads (18%) | catalogued as COSV63286272; called by muse, mutect2, varscan2
- KMT2D | c.12115G>A p.E4039K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as COSV56445756; called by muse, mutect2, varscan2
- LGSN | c.543G>C p.L181F | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.713); catalogued as COSV65727359; called by muse, mutect2, varscan2
- LPP | c.589G>A p.G197R | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as rs372539871; called by muse, mutect2, varscan2
- LRRFIP2 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60867532, COSV60868013; called by muse, mutect2
- MAG | c.188G>A p.S63N | Missense Mutation (SNP) | VAF 63/168 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as rs752139387, COSV62700841, COSV62702443; called by muse, mutect2, varscan2
- MAP3K4 | c.1938G>C p.L646F | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100815060; called by muse, mutect2, varscan2
- MIER3 | c.1420G>A p.E474K (on ENST00000381199 / NM_001297599.2; = p.E473K on NM_152622.4) | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.057); catalogued as COSV67082867; called by muse, mutect2, varscan2
- MMP10 | c.321G>C p.K107N | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV54246411; called by muse, mutect2, varscan2
- MVP | c.2113G>C p.E705Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV62422168; called by muse, mutect2, varscan2
- MYBPC2 | c.1854C>G p.I618M | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV100731601; called by muse, mutect2, varscan2
- MYSM1 | c.1160A>T p.Q387L | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV68977553; called by muse, mutect2, varscan2
- NAALADL1 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs752886257, COSV60523012; called by muse, mutect2, varscan2
- NAV2 | c.6016G>A p.E2006K (on ENST00000396087 / NM_001244963.2; = p.E1947K on NM_145117.5) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV60659902; called by muse, mutect2, varscan2
- NEBL | c.2167C>A p.L723M | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.051); catalogued as COSV65803296; called by muse, mutect2, varscan2
- NEXMIF | c.4452A>C p.K1484N | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV50022095; called by muse, varscan2
- NFASC | c.1075C>T p.R359* (on ENST00000339876 / NM_001378329.1; = p.R370* on NM_015090.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 36/45 reads (80%) | catalogued as COSV100362863; called by muse, mutect2, varscan2
- NLRP8 | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52588395; called by muse, mutect2, varscan2
- NMD3 | c.685C>G p.Q229E | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV63618666; called by muse, mutect2, varscan2
- NUP62 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as rs1330631179, COSV61312253; called by muse, mutect2, varscan2
- NXF3 | c.878C>G p.S293C | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV67703716; called by muse, mutect2, varscan2
- OOEP | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 12/26 reads (46%) | catalogued as COSV64859171; called by muse, mutect2, varscan2
- OR2B3 | c.146G>C p.C49S | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65850974; called by muse, mutect2, varscan2
- OR2T2 | c.339C>G p.F113L | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.15); catalogued as COSV61617737, COSV61618215; called by muse, mutect2, varscan2
- OR51V1 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 35/43 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV58315296; called by muse, mutect2, varscan2
- OSBPL8 | c.82G>A p.V28I | Missense Mutation (SNP) | VAF 31/41 reads (76%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV53883290; called by muse, mutect2, varscan2
- OSR1 | c.280C>G p.H94D | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.4); catalogued as COSV55345658; called by muse, mutect2, varscan2
- PBRM1 | c.4487C>T p.P1496L (on ENST00000296302 / NM_001366071.2; = p.P1389L on NM_018313.5) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56279315; called by muse, mutect2, varscan2
- PFN1 | c.12G>C p.W4C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52591560, COSV99337234; called by muse, mutect2, varscan2
- PHLDB1 | c.3358A>G p.M1120V | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as COSV61878809; called by muse, mutect2, varscan2
- POU3F1 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV65948687; called by muse, mutect2, varscan2
- PRDM10 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); catalogued as COSV62604012; called by muse, mutect2, varscan2
- PSTK | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs750134125, COSV64398319; called by muse, mutect2, varscan2
- PTCH1 | c.4021C>G p.P1341A | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV59476894; called by muse, mutect2, varscan2
- RAB39B | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV65624705; called by muse, mutect2, varscan2
- REM2 | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57465312; called by muse, mutect2, varscan2
- RNASE3 | c.124C>A p.H42N | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58959590, COSV58959934; called by muse, mutect2, varscan2
- SEC31B | c.882G>C p.E294D | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); catalogued as COSV64824805; called by muse, mutect2, varscan2
- SERINC1 | c.530C>T p.S177L | Missense Mutation (SNP) | VAF 43/58 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV60102181; called by muse, mutect2, varscan2
- SGK2 | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as rs1436070727, COSV58313443; called by muse, mutect2, varscan2
- SIK2 | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59253010; called by muse, mutect2, varscan2
- SLC34A3 | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.952); catalogued as COSV63187174; called by muse, mutect2, varscan2
- SLC37A3 | c.1337C>T p.S446F (on ENST00000326232 / NM_001363375.1; = p.V345= on NM_032295.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV58265400; called by muse, mutect2, varscan2
- SLF2 | c.928C>T p.L310F | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV53274290; called by muse, mutect2, varscan2
- SND1 | c.823_824insT p.G275Vfs*61 | Frame Shift Ins (INS) | VAF 16/62 reads (26%) | catalogued as COSV61241679; called by mutect2, pindel, varscan2
- SOCS6 | c.821T>G p.V274G | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV67546500; called by muse, mutect2, varscan2
- SPINT2 | c.564G>C p.E188D | Missense Mutation (SNP) | VAF 44/62 reads (71%) | SIFT tolerated (0.62); PolyPhen benign (0.019); catalogued as COSV100007451, COSV56647969; called by muse, mutect2, varscan2
- SPOCK3 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.027); catalogued as COSV62726899; called by muse, mutect2, varscan2
- SSX1 | c.89C>A p.T30K | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1268993303, COSV65355614; called by muse, mutect2, varscan2
- SUN1 | c.2066C>T p.S689L (on ENST00000405266 / NM_001367651.1; = p.S569L on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747017149, COSV67449802; called by muse, mutect2, varscan2
- TCERG1L | c.1663C>T p.Q555* | Nonsense Mutation (SNP) | VAF 5/64 reads (8%) | catalogued as COSV64051810; called by muse, mutect2, varscan2
- TFAP2C | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52371236; called by muse, mutect2, varscan2
- TJP1 | c.3325C>T p.Q1109* | Nonsense Mutation (SNP) | VAF 18/74 reads (24%) | catalogued as COSV100632356; called by muse, mutect2, varscan2
- TMEM67 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.057); catalogued as rs1432152491, COSV60035754, COSV60043486; called by muse, mutect2, varscan2
- TRANK1 | c.1670A>G p.K557R | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs1054120688, COSV57152102; called by muse, mutect2, varscan2
- TRIM10 | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 65/141 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64989662; called by muse, mutect2, varscan2
- TTC3 | c.3685G>A p.A1229T | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as COSV61290873; called by muse, mutect2, varscan2
- UBE2O | c.3640G>A p.D1214N | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.083); catalogued as COSV60063677; called by muse, mutect2, varscan2
- UBR5 | c.6193G>A p.D2065N | Missense Mutation (SNP) | VAF 11/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55288461; called by muse, mutect2
- UPF1 | c.1114G>A p.E372K (on ENST00000599848 / NM_001297549.2; = p.E361K on NM_002911.4) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV53197387, COSV99438855; called by muse, mutect2, varscan2
- VCAN | c.3098A>T p.E1033V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); catalogued as COSV54106416; called by muse, mutect2, varscan2
- VCAN | c.7019G>C p.G2340A | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0.024); catalogued as COSV54106428, COSV99425782; called by muse, mutect2, varscan2
- VWA7 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV63304584; called by muse, mutect2, varscan2
- VWF | c.8224G>C p.E2742Q | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV54622060; called by muse, mutect2, varscan2
- XIRP2 | c.8329G>C p.E2777Q (on ENST00000628543; = p.E2952Q on NM_152381.6) | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.879); catalogued as COSV54703994, COSV99739855; called by muse, mutect2, varscan2
- ZFHX4 | c.5276C>T p.S1759F | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV50880508; called by muse, mutect2, varscan2
- ZNF10 | c.1337C>T p.S446F | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs774250176, COSV50212538; called by muse, mutect2, varscan2
- ZNF112 | c.2218C>T p.Q740* (on ENST00000337401 / NM_001083335.2; = p.Q734* on NM_013380.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 58/394 reads (15%) | catalogued as COSV100495492; called by muse, mutect2, varscan2
- ZNF415 | c.1571A>T p.Y524F | Missense Mutation (SNP) | VAF 171/334 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as COSV54701788; called by muse, mutect2, varscan2
- ZNF415 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 75/180 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as COSV54701812; called by muse, mutect2, varscan2
- ZNF471 | c.1824C>G p.F608L | Missense Mutation (SNP) | VAF 118/209 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57291508; called by muse, mutect2, varscan2
- ZNF518A | c.1083G>C p.Q361H | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV100283353; called by muse, mutect2
- ZSCAN25 | c.1349G>T p.R450L | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.172); catalogued as COSV53552052, COSV53553204; called by muse, mutect2, varscan2
- ABCA13 | c.760_761dup p.E255Pfs*12 | Frame Shift Ins (INS) | VAF 17/62 reads (27%) | called by mutect2, pindel, varscan2
- RB1 | c.2181_2191del p.Y728Sfs*19 | Frame Shift Del (DEL) | VAF 28/48 reads (58%) | called by pindel, varscan2
- SLC52A2 | c.1202dup p.R402Pfs*43 | Frame Shift Ins (INS) | VAF 34/78 reads (44%) | called by mutect2, pindel, varscan2
- SOCS7 | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- AMHR2 | c.1440G>A p.L480= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as COSV99143026; called by muse, mutect2, varscan2
- ARHGEF11 | c.3360C>T p.F1120= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV59354919; called by muse, mutect2, varscan2
- CCNA1 | c.1111C>T p.L371= | Silent (SNP) | VAF 27/111 reads (24%) | catalogued as COSV55221909; called by muse, mutect2, varscan2
- CD40 | c.583C>T p.L195= | Silent (SNP) | VAF 44/117 reads (38%) | catalogued as COSV100953838, COSV64847858; called by muse, mutect2, varscan2
- CD5L | c.855G>A p.L285= | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as rs747681014, COSV63822146; called by muse, mutect2, varscan2
- CDH10 | c.2127C>T p.D709= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as rs752982862, COSV52581105; called by muse, mutect2, varscan2
- CIDEA | c.87G>C p.P29= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV57598672; called by muse, mutect2, varscan2
- CNTNAP5 | c.3771C>T p.I1257= | Silent (SNP) | VAF 65/116 reads (56%) | catalogued as COSV70488477; called by muse, mutect2, varscan2
- CWH43 | c.1899G>T p.L633= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV56936382, COSV56939399; called by muse, mutect2, varscan2
- DCAF12L2 | c.987C>T p.V329= | Silent (SNP) | VAF 64/77 reads (83%) | catalogued as COSV100758499, COSV63581926; called by muse, mutect2, varscan2
- DCPS | c.294G>A p.L98= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV55011097; called by muse, mutect2, varscan2
- FREM2 | c.198C>T p.V66= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs1364276755, COSV99040141; called by muse, mutect2, varscan2
- GPC4 | c.1308G>A p.V436= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as COSV63698078; called by muse, mutect2, varscan2
- HIGD2A | c.117C>T p.F39= | Silent (SNP) | VAF 25/118 reads (21%) | catalogued as rs764165420, COSV51257658; called by muse, mutect2, varscan2
- ITGAE | c.423C>T p.F141= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV53994846; called by muse, mutect2, varscan2
- ITGAL | c.1614C>T p.D538= | Silent (SNP) | VAF 46/89 reads (52%) | catalogued as rs933657432, COSV63320818, COSV63322484; called by muse, mutect2, varscan2
- MAP4K1 | c.192C>A p.L64= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV50264138; called by muse, mutect2, varscan2
- MATN4 | c.558G>A p.S186= | Silent (SNP) | VAF 23/86 reads (27%) | catalogued as COSV59215613; called by muse, mutect2
- MEIG1 | c.168G>A p.V56= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV65542622; called by muse, mutect2, varscan2
- MST1 | c.2139G>A p.V713= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as rs753842304, COSV56533977; called by muse, mutect2, varscan2
- MYO18B | c.6780G>A p.K2260= | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as rs1472827930, COSV59135822; called by muse, mutect2, varscan2
- MYO5B | c.4290C>T p.Y1430= | Silent (SNP) | VAF 132/404 reads (33%) | catalogued as COSV53220123; called by muse, mutect2, varscan2
- NGF | c.186C>T p.R62= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs780432648, COSV65686832; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NINL | c.3234G>A p.L1078= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as COSV54003247, COSV99625943; called by muse, mutect2, varscan2
- OR8H2 | c.420C>G p.L140= | Silent (SNP) | VAF 36/196 reads (18%) | catalogued as COSV57944960, COSV57946617; called by muse, mutect2, varscan2
- PLCB2 | c.930C>G p.L310= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV53033973; called by muse, mutect2, varscan2
- PMPCA | c.522C>T p.P174= | Silent (SNP) | VAF 55/81 reads (68%) | catalogued as COSV53741778; called by muse, mutect2, varscan2
- PNMT | c.504G>A p.G168= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs1384017060, COSV54093173; called by muse, mutect2, varscan2
- POR | c.498C>T p.L166= | Silent (SNP) | VAF 78/131 reads (60%) | catalogued as COSV67517042; called by muse, mutect2, varscan2
- PPP1R3F | c.2385G>A p.L795= | Silent (SNP) | VAF 16/18 reads (89%) | catalogued as COSV50018527; called by muse, mutect2, varscan2
- RB1 | c.2172T>A p.I724= | Silent (SNP) | VAF 34/50 reads (68%) | catalogued as COSV57309506; called by muse, varscan2
- RNF123 | c.2613C>T p.I871= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV57538826; called by muse, mutect2, varscan2
- RPS4X | c.415C>T p.L139= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as COSV60181687, COSV60181707; called by muse, mutect2, varscan2
- SLC17A3 | c.372C>G p.L124= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV57760175; called by muse, varscan2
- SLC43A1 | c.633G>A p.L211= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV53559178; called by muse, mutect2, varscan2
- TLR1 | c.714G>A p.A238= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs146940675; called by muse, mutect2, varscan2
- TMC5 | c.1288C>T p.L430= (on ENST00000396229 / NM_001105248.1; = p.L184= on NM_024780.5) | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV54904636; called by muse, mutect2, varscan2
- UBE2S | c.123C>A p.T41= | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as rs373374090, COSV52740719; called by muse, mutect2, varscan2
- UPF1 | c.1989C>T p.L663= (on ENST00000599848 / NM_001297549.2; = p.L652= on NM_002911.4) | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs113001728, COSV53197185; called by muse, mutect2, varscan2
- XKR7 | c.924C>T p.F308= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as rs940513266, COSV101629237, COSV73812872; called by muse, mutect2, varscan2
- ZCCHC14 | c.978G>A p.L326= (on ENST00000268616; = p.L463= on NM_015144.3) | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as rs913323943, COSV51886661; called by muse, mutect2, varscan2
- ZSCAN25 | c.1350G>T p.R450= | Silent (SNP) | VAF 32/60 reads (53%) | catalogued as COSV53553215; called by muse, mutect2, varscan2
- SNORD115-42 | n.12G>C | RNA (SNP) | VAF 36/162 reads (22%) | called by muse, mutect2, varscan2
- SSPOP | n.15204A>G | RNA (SNP) | VAF 4/36 reads (11%) | catalogued as COSV65130784; called by muse, mutect2
- WNT3A | c.*816C>T | 3'UTR (SNP) | VAF 27/62 reads (44%) | catalogued as COSV52731326; called by muse, mutect2, varscan2
